CPTAC case C3N-01643 — Larynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Larynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2e0d5e8b-b18a-49ec-8ac2-9be0c74946d9

Demographics
Sex at birth: male; Race: white; Year of birth: 1948; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Larynx, NOS; Age at diagnosis: 68.2 years (24,920 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,925 days (5.3 years); Progression or recurrence: no; Days to last follow up: 1,925 days (5.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.6 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 6; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (6 entries)
- Days to follow up: 465 days (1.3 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 1.
- Days to follow up: 680 days (1.9 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 1.
- Days to follow up: 990 days (2.7 years); Disease response: Tumor Free; Karnofsky performance status: 60; ECOG performance status: 1.
- Days to follow up: 1,460 days (4.0 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,460 days (4.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,925 days (5.3 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 84 kg; Height: 172 cm; BMI: 28.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 54; Cigarettes per day: 40; Tobacco smoking onset year: 1973; Tobacco smoking quit year: 2000; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 27.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01643-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 177 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide C3N-01643-24: Section location: Larynx; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3N-01643-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -13 days; Method of sample procurement: Blood Draw.
